Somatic mutation profile of cancer-model specimen HCM-BROD-0959-C18-85B (3D Organoid, passage 3; aliquot HCM-BROD-0959-C18-85B-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0959-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G4; Age at diagnosis: 66.3 years (24,234 days).
Specimen HCM-BROD-0959-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 452229f4-6e4b-41c1-958b-c697e9ab226b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0959-C18-10A (Blood Derived Normal), aliquot HCM-BROD-0959-C18-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7ca1fa8-7e0c-4b15-ae6d-3c24c6eccc02

The open-access MAF lists 153 somatic variants for this specimen: 112 protein-altering or splice-affecting, 40 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 40, Nonsense Mutation 10, In Frame Del 1, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 218/352 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYLD | c.2299A>T p.K767* | Nonsense Mutation (SNP) | VAF 109/169 reads (64%) | catalogued as rs886040888, CM103649, COSV61098007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 183/186 reads (98%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.914C>T p.A305V (on ENST00000614293; = p.A275V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 384/870 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1238610607; called by muse, mutect2, varscan2
- ABCB5 | c.3086A>G p.D1029G (on ENST00000404938 / NM_001163941.2; = p.D584G on NM_178559.6) | Missense Mutation (SNP) | VAF 181/356 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1423293338; called by muse, mutect2, varscan2
- ACTL9 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 75/254 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs782182119, COSV61006158; called by muse, mutect2, varscan2
- ADAMTS20 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs763907846; called by muse, mutect2, varscan2
- AMBRA1 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 250/252 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV54052815; called by muse, mutect2, varscan2
- AMOTL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 233/235 reads (99%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs773855698, COSV58569235; called by muse, mutect2, varscan2
- ANKRD36B | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51530181, COSV99307786; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 138/140 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs185758992; called by muse, mutect2, varscan2
- BEND7 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 163/626 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61989897; called by muse, mutect2, varscan2
- CDH12 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.116); catalogued as rs768928463, COSV66405593; called by muse, mutect2, varscan2
- CEP112 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs147020220, COSV67137724; called by muse, mutect2, varscan2
- COL22A1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs537744559, COSV57330656; called by mutect2, varscan2
- COL4A6 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 141/146 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170169985; called by muse, mutect2, varscan2
- COL6A1 | c.2693C>T p.T898M | Missense Mutation (SNP) | VAF 445/454 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs752473048; called by muse, mutect2, varscan2
- CPNE8 | c.1475G>C p.R492T | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as COSV100504044, COSV58845078; called by muse, mutect2, varscan2
- CYP4B1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 135/256 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs139750942; called by muse, mutect2, varscan2
- DHH | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 539/1047 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1381598726; called by muse, mutect2, varscan2
- DHX33 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs745955062, COSV56579225; called by muse, mutect2, varscan2
- FAM13A | c.2897G>T p.R966L | Missense Mutation (SNP) | VAF 201/209 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52003043; called by muse, mutect2, varscan2
- FAM187B | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV99048804; called by muse, mutect2, varscan2
- FAM47B | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 191/195 reads (98%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs898061216, COSV61452991; called by muse, mutect2, varscan2
- GREB1 | c.5149G>A p.V1717M | Missense Mutation (SNP) | VAF 160/492 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs377649994; called by muse, mutect2, varscan2
- GUCY1A2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 486/497 reads (98%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1414562428; called by muse, mutect2, varscan2
- H1-5 | c.615_629del p.P213_K217del | In Frame Del (DEL) | VAF 120/274 reads (44%) | catalogued as rs758100284; called by mutect2, varscan2
- ITIH5 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56901066; called by muse, mutect2, varscan2
- JAKMIP1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 423/882 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV99288898; called by muse, mutect2, varscan2
- LEMD1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 156/261 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs772245225; called by muse, mutect2, varscan2
- LIG4 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 38/771 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV63596652; called by muse, mutect2
- MARCO | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 126/416 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs773925484, COSV100503279, COSV59051612; called by muse, mutect2, varscan2
- MIGA2 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 302/626 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs549699802, COSV52978461; called by muse, varscan2
- MYH14 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 226/570 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs535145284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP5L | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 519/1043 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371319353; called by muse, mutect2, varscan2
- NCOA3 | c.3910G>T p.A1304S (on ENST00000371998 / NM_181659.3; = p.A1300S on NM_006534.4) | Missense Mutation (SNP) | VAF 80/490 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV100507221; called by muse, mutect2, varscan2
- NEB | c.7316C>T p.S2439L | Missense Mutation (SNP) | VAF 152/284 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs774282909; called by muse, mutect2, varscan2
- NMUR1 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 329/858 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763514103, COSV59405556; called by muse, mutect2, varscan2
- NTM | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 213/215 reads (99%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs763290433, COSV66204184; called by muse, mutect2, varscan2
- OR4K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 189/302 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150686832, COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- OSBPL3 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 256/551 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs749326073, COSV57655492; called by muse, mutect2, varscan2
- PATJ | c.4849G>T p.G1617C | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57168565; called by muse, mutect2, varscan2
- PGA5 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 330/358 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs200807597; called by muse, mutect2, varscan2
- POSTN | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 131/813 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs775213102, COSV65712393; called by muse, mutect2, varscan2
- RGS6 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 293/725 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs751525654, COSV100664715, COSV59579508; called by muse, mutect2, varscan2
- RHEX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs531574406, COSV58980514; called by muse, mutect2, varscan2
- SARDH | c.2623G>A p.G875S | Missense Mutation (SNP) | VAF 265/532 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs760438211, COSV64100968; called by muse, mutect2, varscan2
- SEMA3F | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 337/343 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756328900, COSV50029351; called by muse, mutect2, varscan2
- SLITRK5 | c.2716G>T p.A906S | Missense Mutation (SNP) | VAF 440/823 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV61522620; called by muse, mutect2, varscan2
- SMTNL1 | c.908G>A p.R303Q (on ENST00000399154; = p.R340Q on NM_001105565.2) | Missense Mutation (SNP) | VAF 460/467 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs372952972; called by muse, mutect2, varscan2
- SPRED3 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 257/482 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs779195105; called by muse, mutect2, varscan2
- STS | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs372945330; called by muse, mutect2, varscan2
- TENM3 | c.7763G>A p.G2588D | Missense Mutation (SNP) | VAF 277/282 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV101305251; called by muse, mutect2, varscan2
- TMC7 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 123/223 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs150991752, COSV99076143; called by muse, mutect2, varscan2
- UGT1A7 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 244/428 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1559339683; called by muse, mutect2, varscan2
- WDR90 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 104/195 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as COSV53469133; called by muse, mutect2, varscan2
- WFS1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 218/1043 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs372783392; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF91 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs965609357, COSV56081376; called by muse, varscan2
- AAR2 | c.756del p.G253Vfs*26 | Frame Shift Del (DEL) | VAF 97/371 reads (26%) | called by mutect2, pindel, varscan2
- AGPAT2 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATM | c.3662G>A p.W1221* | Nonsense Mutation (SNP) | VAF 132/134 reads (99%) | called by muse, mutect2, varscan2
- ATP1A1 | c.1236C>G p.D412E | Missense Mutation (SNP) | VAF 173/376 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- C3 | c.418dup p.T140Nfs*29 | Frame Shift Ins (INS) | VAF 72/242 reads (30%) | called by mutect2, pindel, varscan2
- CCER2 | c.301A>G p.R101G | Missense Mutation (SNP) | VAF 52/495 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CDK15 | c.1083A>C p.E361D (on ENST00000652192 / NM_001366386.2; = p.E310D on NM_139158.2) | Missense Mutation (SNP) | VAF 97/527 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- CES5A | c.1513G>C p.D505H (on ENST00000290567 / NM_001143685.2; = p.D455H on NM_145024.3) | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- CHAMP1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 144/848 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COG6 | c.297G>A p.E99= | Splice Region (SNP) | VAF 36/392 reads (9%) | called by muse, mutect2
- COL12A1 | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 367/371 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DGKI | c.1734A>T p.R578S | Missense Mutation (SNP) | VAF 29/455 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2
- EML4 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 158/250 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ERICH2 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 131/243 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM135B | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 350/498 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171B | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 91/421 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXB2 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 35/722 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GRM4 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, varscan2
- GTSE1 | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HAUS2 | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.173); called by mutect2, varscan2
- HELZ2 | c.2487C>A p.C829* (on ENST00000467148 / NM_001037335.2; = p.C260* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 21/680 reads (3%) | called by muse, mutect2
- HJV | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 414/652 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HMCN2 | c.14150G>A p.C4717Y | Missense Mutation (SNP) | VAF 30/700 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMGCLL1 | c.169T>A p.L57M | Missense Mutation (SNP) | VAF 32/618 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2
- IGF2R | c.4663G>T p.E1555* | Nonsense Mutation (SNP) | VAF 55/477 reads (12%) | called by muse, mutect2, varscan2
- JSRP1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 270/450 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- KLHL29 | c.2359T>G p.Y787D | Missense Mutation (SNP) | VAF 286/436 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2
- LDLRAD4 | c.729C>A p.S243R | Missense Mutation (SNP) | VAF 162/1012 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP4K4 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- MEPCE | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 420/1159 reads (36%) | called by muse, mutect2, varscan2
- MUC16 | c.10987T>A p.L3663M | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NOL4L | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NTN5 | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 228/579 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PDE3B | c.2082G>C p.R694S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PHF14 | c.1678G>T p.V560F | Missense Mutation (SNP) | VAF 65/461 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PTAR1 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 217/453 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRK | c.2879G>T p.G960V (on ENST00000368215 / NM_001291984.2; = p.G961V on NM_002844.4) | Missense Mutation (SNP) | VAF 305/308 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REX1BD | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 399/669 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RIMS2 | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RRAGB | c.613C>T p.R205* (on ENST00000262850 / NM_016656.4; = p.R177* on NM_006064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 88/90 reads (98%) | called by muse, mutect2, varscan2
- SBNO1 | c.3858C>A p.C1286* (on ENST00000420886; = p.C1285* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 29/214 reads (14%) | called by muse, mutect2, varscan2
- SEMA3E | c.1586G>T p.C529F | Missense Mutation (SNP) | VAF 122/649 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC39A7 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 255/515 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SMG5 | c.909C>G p.S303R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TAF1L | c.4492G>T p.E1498* | Nonsense Mutation (SNP) | VAF 55/474 reads (12%) | called by muse, mutect2, varscan2
- TMEM266 | c.1355G>T p.C452F | Missense Mutation (SNP) | VAF 185/956 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TMPRSS9 | c.2996G>A p.R999Q (on ENST00000648592; = p.R965Q on NM_182973.2) | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TPR | c.4478T>G p.L1493R | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- TTN | c.18171G>T p.R6057S (on ENST00000591111; = p.R5130S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/316 reads (5%) | PolyPhen benign (0.053); called by muse, mutect2
- UHMK1 | c.719A>G p.K240R | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- UVSSA | c.754T>G p.C252G | Missense Mutation (SNP) | VAF 473/1010 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDFY3 | c.8095G>A p.E2699K | Missense Mutation (SNP) | VAF 142/146 reads (97%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ZNF189 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 68/578 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZSCAN31 | c.1152C>A p.C384* | Nonsense Mutation (SNP) | VAF 93/184 reads (51%) | called by muse, mutect2, varscan2
- AMPD3 | c.2112C>T p.S704= (on ENST00000396553 / NM_001025389.2; = p.S713= on NM_000480.3) | Silent (SNP) | VAF 60/219 reads (27%) | catalogued as rs752630433, COSV67332332; called by muse, mutect2, varscan2
- ANKRD18B | c.1314T>C p.A438= | Silent (SNP) | VAF 24/564 reads (4%) | called by muse, mutect2
- C22orf23 | c.237C>T p.A79= | Silent (SNP) | VAF 223/225 reads (99%) | called by muse, mutect2, varscan2
- CCN6 | c.480G>T p.L160= | Silent (SNP) | VAF 44/590 reads (7%) | called by muse, mutect2
- CD1D | c.999C>T p.G333= | Silent (SNP) | VAF 180/306 reads (59%) | catalogued as rs1473349997, COSV63809340; called by muse, mutect2, varscan2
- CDKL5 | c.615C>T p.S205= | Silent (SNP) | VAF 160/163 reads (98%) | catalogued as rs1273092102; called by muse, mutect2, varscan2
- CLRN2 | c.381G>A p.P127= | Silent (SNP) | VAF 286/612 reads (47%) | catalogued as rs374029760; called by muse, mutect2, varscan2
- CNTN1 | c.360C>T p.Y120= | Silent (SNP) | VAF 153/354 reads (43%) | catalogued as rs572299257, COSV61638568; called by muse, mutect2, varscan2
- COL22A1 | c.576C>T p.P192= | Silent (SNP) | VAF 758/1050 reads (72%) | called by muse, mutect2, varscan2
- COL2A1 | c.1353G>A p.P451= | Silent (SNP) | VAF 198/423 reads (47%) | catalogued as rs560149744, COSV61535859; called by muse, mutect2, varscan2
- COL5A1 | c.3897C>T p.G1299= | Silent (SNP) | VAF 300/648 reads (46%) | catalogued as rs745918663; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DGKH | c.981G>A p.S327= | Silent (SNP) | VAF 207/429 reads (48%) | catalogued as rs753953792, COSV54930103; called by muse, mutect2, varscan2
- DTNB | c.1116C>T p.A372= | Silent (SNP) | VAF 186/296 reads (63%) | catalogued as rs755885793; called by muse, mutect2, varscan2
- DYNC1LI2 | c.885C>T p.H295= | Silent (SNP) | VAF 81/348 reads (23%) | called by muse, mutect2, varscan2
- GOLGA8H | c.360A>C p.A120= | Silent (SNP) | VAF 133/324 reads (41%) | called by muse, mutect2, varscan2
- GPR85 | c.51T>A p.P17= | Silent (SNP) | VAF 34/614 reads (6%) | called by muse, mutect2
- HOXB3 | c.759C>A p.A253= | Silent (SNP) | VAF 181/367 reads (49%) | called by muse, mutect2, varscan2
- IRAK3 | c.1284G>A p.T428= | Silent (SNP) | VAF 370/522 reads (71%) | catalogued as rs373101549; called by muse, mutect2, varscan2
- KCNH1 | c.1221C>T p.D407= (on ENST00000271751 / NM_172362.3; = p.D380= on NM_002238.4) | Silent (SNP) | VAF 195/339 reads (58%) | catalogued as rs138866428; called by muse, mutect2, varscan2
- KLK2 | c.660T>C p.N220= | Silent (SNP) | VAF 181/305 reads (59%) | called by muse, mutect2, varscan2
- LCN6 | c.213G>A p.T71= | Silent (SNP) | VAF 248/514 reads (48%) | catalogued as rs776445939; called by muse, varscan2
- MMP16 | c.1162T>C p.L388= | Silent (SNP) | VAF 125/654 reads (19%) | catalogued as COSV54175920, COSV54189671, COSV99691040; called by muse, mutect2, varscan2
- MUC12 | c.11886C>A p.T3962= (on ENST00000379442; = p.T3819= on NM_001164462.1) | Silent (SNP) | VAF 684/686 reads (100%) | called by mutect2, varscan2
- MYO10 | c.5142C>T p.I1714= | Silent (SNP) | VAF 58/628 reads (9%) | called by muse, mutect2
- OR4K15 | c.855C>T p.P285= (on ENST00000305051; = p.P261= on NM_001005486.1) | Silent (SNP) | VAF 63/485 reads (13%) | called by muse, mutect2, varscan2
- OR6N1 | c.931T>C p.L311= | Silent (SNP) | VAF 60/154 reads (39%) | called by muse, mutect2, varscan2
- PATJ | c.4848T>G p.A1616= | Silent (SNP) | VAF 60/252 reads (24%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.2019G>A p.A673= | Silent (SNP) | VAF 424/429 reads (99%) | catalogued as rs776657082; called by muse, mutect2, varscan2
- PLEC | c.9723G>T p.G3241= (on ENST00000322810 / NM_201380.4; = p.G3131= on NM_000445.5) | Silent (SNP) | VAF 62/1132 reads (5%) | called by muse, mutect2
- PMCH | c.474C>G p.V158= | Silent (SNP) | VAF 97/190 reads (51%) | catalogued as rs759732671; called by muse, mutect2, varscan2
- PPIAL4G | c.468C>A p.I156= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs1273938457; called by muse, mutect2, varscan2
- RBMXL2 | c.906C>T p.Y302= | Silent (SNP) | VAF 328/334 reads (98%) | catalogued as rs774916563, COSV100182057; called by muse, varscan2
- REXO4 | c.903C>G p.L301= | Silent (SNP) | VAF 56/429 reads (13%) | catalogued as rs1554780278; called by muse, mutect2
- SPIDR | c.2631A>C p.G877= | Silent (SNP) | VAF 302/489 reads (62%) | called by muse, mutect2, varscan2
- SVEP1 | c.7590C>T p.L2530= | Silent (SNP) | VAF 263/605 reads (43%) | catalogued as rs369617735; called by muse, mutect2, varscan2
- THSD4 | c.516C>A p.A172= | Silent (SNP) | VAF 75/422 reads (18%) | called by muse, mutect2, varscan2
- TRIM50 | c.531C>T p.R177= | Silent (SNP) | VAF 307/713 reads (43%) | catalogued as rs1194371507; called by muse, mutect2, varscan2
- VPS51 | c.1362G>C p.L454= | Silent (SNP) | VAF 145/353 reads (41%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.78C>T p.L26= | Silent (SNP) | VAF 558/565 reads (99%) | catalogued as rs751582921; called by muse, mutect2, varscan2
- ZFHX4 | c.1668C>A p.G556= | Silent (SNP) | VAF 343/502 reads (68%) | catalogued as rs1438067671; called by muse, mutect2, varscan2
- TREX2 | c.-290G>C | 5'UTR (SNP) | VAF 271/282 reads (96%) | called by muse, mutect2, varscan2
